Somatic mutation profile of tumor specimen TCGA-FU-A2QG-01A (aliquot TCGA-FU-A2QG-01A-11D-A18J-09) from TCGA case TCGA-FU-A2QG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 29.7 years (10,865 days).
Specimen TCGA-FU-A2QG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3be5677-a665-43d5-a164-3156e6843e89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A2QG-10A (Blood Derived Normal), aliquot TCGA-FU-A2QG-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfa3d236-755c-4dc5-b18d-26c01a76f8e5

The open-access MAF lists 92 somatic variants for this specimen: 60 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 30, Nonsense Mutation 6, RNA 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASGR1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52649331; called by muse, mutect2, varscan2
- ATP2B4 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as rs567340474, COSV58177450; called by muse, mutect2, varscan2
- BPTF | c.3548C>A p.S1183* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV58842665, COSV58843504; called by muse, mutect2, varscan2
- C8G | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as rs771007346, COSV56403613; called by mutect2, varscan2
- CBARP | c.981C>G p.F327L (on ENST00000382477; = p.F307L on NM_152769.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as COSV53070545, COSV53070779; called by muse, mutect2, varscan2
- CIAO3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV52400498; called by muse, mutect2, varscan2
- CMKLR1 | c.868C>T p.P290S (on ENST00000312143 / NM_001142344.2; = p.P288S on NM_004072.3) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV56437134, COSV56440564; called by muse, mutect2, varscan2
- COL9A1 | c.580C>G p.L194V | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61832411, COSV61835355; called by muse, mutect2, varscan2
- CPSF2 | c.1838C>G p.S613* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV54099411; called by muse, mutect2, varscan2
- CSF2RB | c.2630T>C p.L877P | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53259538; called by muse, mutect2, varscan2
- DOT1L | c.3603G>C p.E1201D | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.167); catalogued as COSV67111878; called by muse, mutect2, varscan2
- FBXW7 | c.1498C>G p.H500D (on ENST00000281708 / NM_001349798.2; = p.H420D on NM_018315.5) | Missense Mutation (SNP) | VAF 45/57 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55891879, COSV55923194, COSV55937041; called by muse, mutect2, varscan2
- FOLR3 | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100281885, COSV61530628; called by muse, mutect2, varscan2
- FSIP2 | c.18622G>A p.D6208N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV58093215; called by muse, mutect2, varscan2
- GANAB | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs377690186; called by muse, mutect2, varscan2
- GNA13 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200032909, COSV101457429; called by muse, mutect2
- GRIA3 | c.989A>G p.D330G | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52072216; called by muse, mutect2, varscan2
- H2AC16 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58900822; called by muse, mutect2, varscan2
- KRT6B | c.501C>G p.I167M | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV52885190; called by muse, mutect2, varscan2
- LAMA5 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as rs139764752; called by muse, mutect2, varscan2
- LRP4 | c.5309G>A p.R1770Q | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs150211735; called by muse, mutect2, varscan2
- MAP2K3 | c.50G>C p.G17A | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.033); catalogued as COSV57570976, COSV57573018; called by muse, mutect2
- MKI67 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 47/60 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs149160550; called by muse, mutect2, varscan2
- MON1B | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 25/46 reads (54%) | catalogued as COSV50245827; called by muse, mutect2, varscan2
- MUC16 | c.32369C>T p.S10790L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.351); catalogued as COSV101197798, COSV67480339; called by muse, mutect2, varscan2
- MYO7B | c.4984G>A p.D1662N | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs772019402, COSV67347326; called by muse, mutect2, varscan2
- NCR1 | c.35-1G>A p.X12_splice | Splice Site (SNP) | VAF 29/79 reads (37%) | catalogued as COSV52555672; called by muse, mutect2, varscan2
- NLRP4 | c.2573C>G p.S858C | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV56719038; called by muse, mutect2, varscan2
- NSD1 | c.2201A>G p.K734R | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.075); catalogued as COSV61780221; called by muse, mutect2, varscan2
- NUP98 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV61435713; called by muse, mutect2, varscan2
- OPN5 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV55246606; called by muse, mutect2, varscan2
- PLCL2 | c.1352G>A p.R451Q (on ENST00000615277 / NM_001144382.2; = p.R325Q on NM_015184.5) | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.826); catalogued as rs955480597, COSV67623878; called by muse, mutect2, varscan2
- PLCZ1 | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751805291, COSV56856433; called by muse, mutect2, varscan2
- PLSCR3 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs776982633, COSV61171536; called by muse, mutect2, varscan2
- POLR2L | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as COSV58990383, COSV58990492; called by muse, varscan2
- PRXL2C | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs1353315247, COSV100925122; called by muse, varscan2
- PTPRN2 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs761746319, COSV67022348; called by muse, mutect2, varscan2
- RAG1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs763843831, COSV55023805; called by muse, mutect2, varscan2
- RRBP1 | c.2134G>A p.E712K (on ENST00000377813 / NM_001365613.2; = p.E279K on NM_004587.3) | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55704435; called by muse, mutect2, varscan2
- RTF1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV67478516; called by muse, varscan2
- RTF1 | c.602A>T p.E201V | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101047824, COSV67478521; called by muse, varscan2
- RUSC2 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as rs776211425, COSV63429618; called by muse, mutect2, varscan2
- SHC1 | c.456C>A p.N152K (on ENST00000368445 / NM_183001.5; = p.N42K on NM_003029.5) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.164); catalogued as COSV100460553, COSV58315695; called by muse, mutect2
- SIGLEC14 | c.592C>A p.L198I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV55781785; called by muse, mutect2, varscan2
- SMR3A | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 92/109 reads (84%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.013); catalogued as COSV56950683; called by muse, mutect2, varscan2
- SNRK | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56065819, COSV56069721; called by muse, mutect2, varscan2
- SPTBN4 | c.6007G>T p.E2003* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100152429, COSV58955212; called by muse, mutect2, varscan2
- SPTLC1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52765485; called by muse, mutect2, varscan2
- ST7L | c.241T>A p.Y81N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99582944; called by muse, mutect2
- TANC2 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67338091; called by muse, mutect2, varscan2
- TMEM87A | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56198618; called by muse, mutect2, varscan2
- TRPM3 | c.1321G>A p.D441N (on ENST00000357533 / NM_001366142.2; = p.D286N on NM_020952.6) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV62590837; called by muse, mutect2, varscan2
- UBE3B | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs1410764028, COSV55096025; called by muse, mutect2, varscan2
- UBOX5 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as rs1218580602, COSV53907743; called by muse, mutect2, varscan2
- ZBBX | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV56795780; called by muse, mutect2, varscan2
- ZBTB18 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV62397999; called by muse, mutect2, varscan2
- ZNF24 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs757349943, COSV54349019; called by muse, mutect2, varscan2
- ZNF260 | c.1234C>G p.H412D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV72951265; called by muse, mutect2
- ZNF284 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV69691035, COSV69691423; called by muse, mutect2, varscan2
- ZNF559 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs763226737, COSV104396034, COSV57836556; called by muse, mutect2, varscan2
- CIAO3 | c.1200G>A p.L400= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs773793404, COSV52403473; called by muse, mutect2, varscan2
- CYFIP2 | c.33G>T p.L11= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV100555838; called by muse, mutect2
- DNAH1 | c.5235C>G p.L1745= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV70232696; called by muse, mutect2, varscan2
- DNAH10 | c.340C>T p.L114= (on ENST00000409039; = p.L53= on NM_207437.3) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs532577289, COSV68997942; called by muse, mutect2, varscan2
- EXD3 | c.1995C>T p.A665= | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs776730395, COSV59810338; called by muse, mutect2, varscan2
- IGHV4-39 | c.57G>A p.A19= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as rs113892460; called by muse, mutect2, varscan2
- KHDRBS3 | c.489C>T p.I163= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV104419633, COSV63423226; called by muse, mutect2, varscan2
- KRT6B | c.684C>T p.I228= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as rs370270393; called by muse, mutect2, varscan2
- LAMA5 | c.3954C>T p.L1318= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV53365953; called by muse, mutect2, varscan2
- NSD1 | c.2340G>C p.S780= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV61780227; called by muse, mutect2, varscan2
- NSD1 | c.2592G>A p.L864= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV61780246; called by muse, varscan2
- NSD1 | c.2688G>A p.Q896= | Silent (SNP) | VAF 20/28 reads (71%) | catalogued as COSV100728550; called by muse, varscan2
- NSD1 | c.2898G>A p.E966= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as COSV61780255; called by muse, mutect2, varscan2
- PABPN1 | c.762C>T p.I254= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99391110; called by muse, mutect2, varscan2
- PIK3C2A | c.24C>T p.S8= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs776170420, COSV56405055; called by muse, mutect2, varscan2
- POLR2E | c.174C>A p.L58= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV53124807; called by muse, mutect2, varscan2
- RAP1GAP2 | c.126G>A p.R42= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV54583188; called by muse, mutect2, varscan2
- SCN1A | c.5052C>T p.Y1684= (on ENST00000303395 / NM_001202435.3; = p.Y1673= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as rs1433806086, CM113358, COSV57679391; called by muse, mutect2, varscan2
- SLC45A1 | c.813C>T p.L271= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs766341691, COSV57098190; called by muse, mutect2, varscan2
- SULT6B1 | c.651T>A p.I217= (on ENST00000535679 / NM_001367551.1; = p.I179= on NM_001032377.2) | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV53195480; called by muse, mutect2, varscan2
- TENM4 | c.6141G>A p.Q2047= | Silent (SNP) | VAF 43/114 reads (38%) | catalogued as COSV53650627; called by muse, mutect2, varscan2
- TESMIN | c.705C>G p.L235= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV54834003; called by muse, mutect2, varscan2
- THADA | c.1545G>A p.E515= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV57688850; called by muse, mutect2, varscan2
- TLK2 | c.2007G>T p.V669= (on ENST00000326270 / NM_001284333.2; = p.V647= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV58303440; called by muse, mutect2
- TRPM2 | c.3237C>T p.A1079= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs372801595, COSV55973477; called by muse, mutect2, varscan2
- UBL4B | c.495G>A p.E165= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs746703669, COSV61944574; called by muse, mutect2, varscan2
- WDR93 | c.1368T>C p.C456= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as COSV51533931; called by muse, mutect2, varscan2
- XPR1 | c.1851G>C p.L617= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV62558847; called by muse, mutect2, varscan2
- ZNF217 | c.9G>A p.S3= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs200038482, COSV100184251, COSV56598056; called by muse, mutect2, varscan2
- ZXDA | c.1311G>A p.L437= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV62388442, COSV62388976; called by muse, mutect2, varscan2
- ANKRD13D | c.*1689C>T | 3'UTR (SNP) | VAF 18/62 reads (29%) | catalogued as COSV57385869; called by muse, mutect2, varscan2
- MIR205 | n.35C>T | RNA (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
